Gene-level copy-number profile of tumor specimen TCGA-GN-A8LL-06A from TCGA case TCGA-GN-A8LL, project TCGA-SKCM (Skin Cutaneous Melanoma). Sex at birth: female; Vital status: Dead; Primary diagnosis: Malignant melanoma, NOS; Tissue or organ of origin: Skin, NOS; Age at diagnosis: 69.0 years (25,209 days).
Specimen TCGA-GN-A8LL-06A: Sample type: Metastatic; Tissue type: Tumor; Tumor descriptor: Metastatic; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-SKCM.c1e5d785-d738-44a6-9cb6-c363fbd2da26.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-GN-A8LL-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 819 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/661cb844-ccbb-424b-9857-b22f9498b82a

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 28; copy number 1: 17,666; copy number 2: 29,501; copy number 3: 9,124; copy number 4: 1,208; copy number 5: 1,364; copy number 6: 480; copy number 7: 299; copy number 8: 14; copy number 9: 26; copy number 11: 94.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-GN-A8LL-06A-21D-A371-01): tumor purity 0.93, ploidy 2.04, whole-genome doublings 0.

Homozygous deletions (total copy number 0; autosomes only): 28 genes in 3 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr3:116,552,473–116,723,581, 5 genes: LINC00903, RN7SL582P, BZW1P2, TUSC7, AC108713.1.
- chr7:15,611,212–16,706,523, 18 genes (within-gene range 0–1): MEOX2, AC005550.2, LINC02587, AC005550.1, RPL36AP26, AC006041.2, AC006041.1, CRPPA, RPL36AP29, CRPPA-AS1, SOSTDC1, AC005014.3, LRRC72, AC005014.1, AC005014.2, ANKMY2, AC005014.4, BZW2.
- chr13:90,890,954–91,272,577, 5 genes: LINC00410, BRK1P2, LINC00380, LINC00379, PPIAP23.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 2,277 genes in 46 contiguous regions (the 40 largest listed; coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:157,993,273–158,177,755, 5 genes, copy number 6 (within-gene range 3–6): KIRREL1, KIRREL1-IT1, SMIM42, LINC01704, ELL2P1.
- chr1:160,932,465–162,979,793, 85 genes, copy number 7 (within-gene range 4–7) (broad region; genes not listed).
- chr3:22,811,390–30,010,391, 78 genes, copy number 5–6 (broad region; genes not listed).
- chr3:30,697,661–34,677,247, 59 genes, copy number 5 (within-gene range 1–5): AC096921.2, GADL1, MIR466, CNN2P6, RNA5SP127, H3P11, THRAP3P1, STT3B, OSBPL10, OSBPL10-AS1, ZNF587P1, ZNF860, RPL21P40, AC094019.1, Y_RNA, NIFKP7, GPD1L, AC094019.2, RPSAP11, AC097639.1, CMTM8, AC097639.2, KRT18P15, CMTM7, CMTM6, MIR548AY, AC104306.1, DYNC1LI1, AC104306.2, IGBP1P3, RPL30P4, CNOT10, CNOT10-AS1, SUGT1P2, RPL23AP43, TRIM71, CCR4, GLB1, SEC13P1, SUMO2P10, TMPPE, RN7SL296P, CRTAP, AC112211.1, SUSD5, AC123900.1, FBXL2, UBP1, RNU7-110P, RNA5SP128, CLASP2, COX6CP10, AC112220.1, SDAD1P3, AC112220.2, PDCD6IP, LINC01811, AC123023.2, AC123023.1.
- chr3:54,874,605–77,811,844, 276 genes, copy number 5 (broad region; genes not listed).
- chr3:184,174,689–188,003,990, 104 genes, copy number 5–6 (broad region; genes not listed).
- chr4:6,026,199–8,158,832, 44 genes, copy number 5: JAKMIP1, AC092442.1, AC113615.2, LINC02495, AC113615.1, AC116317.2, WFS1, AC116317.1, PPP2R2C, MAN2B2, MRFAP1, LINC02482, AC093323.4, AC093323.1, LINC02481, AC093323.2, S100P, AC093323.3, MRFAP1L1, BLOC1S4, AC106045.1, KIAA0232, TBC1D14, AC097382.3, AC097382.1, RN7SKP292, AC097382.2, CCDC96, TADA2B, GRPEL1, LINC02447, RN7SKP36, SORCS2, MIR4798, PSAPL1, MIR4274, AFAP1-AS1, AFAP1, AC112254.1, AC097381.1, ABLIM2, MIR95, AC097381.3, AC097381.2.
- chr4:8,558,725–8,619,761, 2 genes, copy number 6 (within-gene range 3–6): GPR78, CPZ.
- chr4:15,469,865–16,512,187, 23 genes, copy number 5: CC2D2A, AC007016.1, AC116651.1, FBXL5, FAM200B, AC114744.2, BST1, AC114744.1, AC005798.1, CD38, HPRT1P1, FGFBP1, FGFBP2, PROM1, AC108063.2, TAPT1, AC108063.1, TAPT1-AS1, RPS21P4, AC006427.1, AC006427.2, ZEB2P1, AC097515.1.
- chr4:20,037,560–33,238,670, 111 genes, copy number 5 (broad region; genes not listed).
- chr4:34,657,606–35,496,003, 5 genes, copy number 6: AC093689.1, AC093913.1, AC020589.1, SEC63P2, RNU6-573P.
- chr4:36,426,366–39,485,109, 51 genes, copy number 7: MIR1255B1, LINC02505, AC125336.1, AC093746.1, LINC02616, AL136537.1, MIR4801, NWD2, C4orf19, AC022463.1, AC027607.1, RELL1, Y_RNA, AC108022.1, PGM2, AC021106.2, AC021106.1, TBC1D1, PTTG2, PSME2P4, MRPS33P2, AC098680.2, AC098680.1, LINC02513, AC024023.1, LINC01258, LINC01259, LINC02278, KLF3-AS1, AC021860.1, KLF3, RNA5SP158, TLR10, TLR1, TLR6, FAM114A1, MIR574, TMEM156, KLHL5, AC079921.1, AC079921.2, WDR19, RFC1, RNU6-32P, RNU6-887P, KLB, MIR5591, Y_RNA, RPL9, LIAS, AC021148.1.
- chr4:41,981,756–47,593,486, 58 genes, copy number 5–6: DCAF4L1, AC106052.1, SLC30A9, ATP1B1P1, BEND4, AC111006.1, AC024022.1, SHISA3, ATP8A1, RPS7P7, CCNL2P1, AC096734.2, AC096734.1, RN7SKP82, GRXCR1, AC111198.1, AC097451.1, AC098590.2, AC098590.1, LINC02383, AC114774.1, RN7SL691P, AC080132.1, RN7SL193P, NDUFB4P12, AC114757.1, LINC02475, KCTD8, AC093852.1, YIPF7, GUF1, GNPDA2, AC096586.2, AC096586.1, AC093755.1, PRDX4P1, AC108467.2, AC108467.1, THAP12P9, AC108043.1, RNU6-931P, RN7SKP199, GABRG1, AC104072.1, GABRA2, AC095060.1, RNU6-412P, RAC1P2, COX7B2, GABRA4, GABRB1, AC107398.3, COMMD8, AC107398.4, AC107398.5, ATP10D, AC107398.1, AC107398.2.
- chr11:32,892,811–36,232,136, 70 genes, copy number 7 (within-gene range 3–7) (broad region; genes not listed).
- chr11:56,576,736–58,005,705, 69 genes, copy number 5 (broad region; genes not listed).
- chr11:58,026,706–58,078,603, 6 genes, copy number 5: RNU6-899P, OR6Q1, VN2R9P, AP004247.2, AP004247.1, OR9L1P.
- chr11:60,699,585–61,938,000, 62 genes, copy number 5 (broad region; genes not listed).
- chr11:69,294,151–69,819,416, 15 genes, copy number 5: MYEOV, IFITM9P, AP005233.2, AP005233.1, AP000439.2, AP000439.1, AP000439.3, LINC02747, LINC01488, CCND1, LTO1, FGF19, DNAJB6P5, FGF4, FGF3.
- chr11:71,833,200–79,441,030, 243 genes, copy number 5–11 (broad region; genes not listed).
- chr11:81,821,272–82,733,864, 7 genes, copy number 5: MIR4300HG, AP002802.2, MIR4300, AP002802.1, AP000793.1, RPS28P7, FAM181B.
- chr11:89,177,875–89,301,477, 4 genes, copy number 5: TYR, CBX3P7, AP000720.1, AP000720.2.
- chr11:101,765,935–102,233,424, 8 genes, copy number 5 (within-gene range 4–5): AP000776.1, ANGPTL5, CEP126, CFAP300, RNA5SP535, AP001527.1, AP001527.2, YAP1.
- chr11:103,045,237–107,177,530, 55 genes, copy number 6: AP001486.1, DCUN1D5, AP001486.2, DYNC2H1, AP002961.1, MTCO3P15, MTATP6P15, MTCO2P15, MTCO1P15, MTND2P26, MTND1P36, AP003461.1, AP002989.1, MIR4693, PDGFD, AP003043.1, DDI1, AP003304.1, LINC02552, AP001485.1, AP002004.1, CASP12, CASP4LP, CASP4, AP001153.1, CASP5, CASP1, CARD16, AP001153.2, CASP1P2, CARD17, CASP1P1, CARD18, OR2AL1P, AP003181.1, Metazoa_SRP, GRIA4, HSPD1P13, RNU4-55P, RNU6-277P, AP000813.1, MSANTD4, KBTBD3, AASDHPPT, AP001001.1, AP001001.2, LINC02719, AP002001.3, AP002001.1, AP002001.2, AP003173.1, GUCY1A2, AP001282.2, AP001282.1, ASS1P13.
- chr12:66,767–3,593,973, 90 genes, copy number 5 (broad region; genes not listed).
- chr12:3,610,307–3,612,003, 1 gene, copy number 5: AC005831.1.
- chr12:3,791,047–4,774,184, 24 genes, copy number 5 (within-gene range 3–5): PARP11, OTUD4P1, PARP11-AS1, AC084375.1, HSPA8P5, AC007207.1, CCND2-AS1, CCND2, AC008012.1, TIGAR, AC006122.1, FGF23, FGF6, C12orf4, RAD51AP1, DYRK4, AC005832.2, AC005832.4, AKAP3, AC005832.3, AC005832.1, NDUFA9, AC005833.1, GAU1.
- chr12:8,076,939–11,310,436, 167 genes, copy number 5–7 (within-gene range 3–7) (broad region; genes not listed).
- chr12:12,813,316–13,142,521, 16 genes, copy number 6 (within-gene range 3–6): DDX47, AC007215.1, AC007688.2, RPL13AP20, GPRC5A, MIR614, GPRC5D-AS1, GPRC5D, AC007688.3, AC007688.1, HEBP1, HTR7P1, AC023790.2, AC023790.1, FAM234B, GSG1.
- chr12:15,001,787–15,006,999, 1 gene, copy number 5: LINC01489.
- chr12:15,112,363–15,114,698, 1 gene, copy number 5: RERG-IT1.
- chr12:15,439,527–15,440,401, 1 gene, copy number 6: AC092183.1.
- chr12:17,673,299–24,562,544, 81 genes, copy number 5–8 (within-gene range 3–8) (broad region; genes not listed).
- chr15:91,853,708–99,733,561, 148 genes, copy number 5–7 (broad region; genes not listed).
- chr15:101,495,052–101,933,350, 22 genes, copy number 6: AC090164.2, AC090164.3, AC090164.4, SNRPCP18, AC090164.1, LINC02348, TM2D3, RNU6-807P, TARS3, AC027559.1, DNM1P47, GOLGA8VP, RN7SL209P, OR4F6, OR4F15, OR4F14P, OR4F13P, OR4F28P, WBP1LP5, AC140725.2, OR4F4, OR4G2P.
- chr18:33,851,100–36,829,216, 48 genes, copy number 6 (within-gene range 4–6): NOL4, Y_RNA, AC104985.3, AC104985.1, AC104985.2, DTNA, AC013290.1, AC022601.1, AC068506.1, MAPRE2, AC015967.2, AC015967.1, ZNF397, ZSCAN30, AC011815.3, AC011815.2, AC011815.1, ZNF271P, AC116447.1, ZNF24, ZNF396, AC007998.1, AC007998.4, AC007998.3, AC007998.2, INO80C, AC007998.5, GALNT1, MIR3975, AC090220.1, AC090229.1, NRBF2P1, MIR187, MIR3929, AC118757.1, AC091060.1, C18orf21, RPRD1A, SLC39A6, ELP2, AC023043.1, MOCOS, AC023043.4, AC023043.2, AC023043.3, FHOD3, AC055840.1, TPGS2.
- chr18:68,258,080–68,278,243, 2 genes, copy number 5: LINC01912, AC022968.1.
- chr20:3,927,309–7,371,692, 72 genes, copy number 5 (within-gene range 3–5) (broad region; genes not listed).
- chr22:16,783,412–16,856,162, 5 genes, copy number 5 (within-gene range 3–5): XKR3, HSFY1P1, GPM6BP3, AC007064.4, AC007064.3.
- chr22:33,014,980–33,145,861, 3 genes, copy number 5 (within-gene range 3–5): Z83846.1, LINC01640, Z82198.1.
- chr22:36,467,046–39,532,761, 149 genes, copy number 5 (within-gene range 2–5) (broad region; genes not listed).

Autosomal genes at a single copy (total copy number 1): 16,524. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
